Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A1QB, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A1QB-06A (Metastatic).

[page 1 of 2]
1CD-0-3
Melanoma, NOS 8720/3
Site: lymph node, NOS C77.9
3/15/11 *ms*

DIAGNOSIS

- (A) LEFT SUPERFICIAL INGUINAL LYMPH NODES WITH OVERLYING SKIN:
METASTATIC MALIGNANT MELANOMA IN TWO OF THREE LYMPH NODES.
- (B) INTRANSIT MELANOMA OF LEFT MEDIAL THIGH:
MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE.
- (C) INTRANSIT NODULE, LEFT PROXIMAL CALF:
MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE (TWO NODULES).
- (D) INTRANSIT METASTASIS, LEFT MEDIAL CONDYLE:
MALIGNANT MELANOMA IN SUBCUTANEOUS TISSUE.

Entire report and diagnosis completed by MD

	Yes	No
Site:		

GROSS DESCRIPTION

(A) LEFT SUPERFICIAL INGUINAL LYMPH NODE WITH OVERLYING SKIN - Received is an irregular piece of fibroadipose tissue (8.0 x 5.5 x 2.0 cm) with overlying unremarkable skin (7.5 x 1.2 cm). One grossly positive lymph node is identified (3.0 x 1.5 x 1.5 cm). Three additional possible lymph nodes are identified (0.2 to 0.5 cm in greatest dimension).

SECTION CODE: A1, overlying skin; A2, one grossly positive lymph node (representative section); A3, one possible lymph node; A4, one possible lymph node; A5, one possible lymph node, serially sectioned, entirely submitted.

(B) INTRANSIT MELANOMA OF LEFT MEDIAL THIGH- A tan-white nonoriented ellipse of skin (6.0 x 1.0 x 2.0 cm). The surface of the specimen appears grossly unremarkable. The specimen is serially sectioned and a dark brown nodule (2.0 x 1.5 x 1.5 cm) is identified.

SECTION CODE: B1, representative sections of the skin; B2, nodule, totally submitted.

(C) INTRANSIT NODULE LEFT PROXIMAL - A tan-white nonoriented ellipse of skin (7.0 x 3.0 x 2.0 cm). On the surface of the specimen, is a healed scar (5.0 cm in length). The specimen is serially sectioned and two dark brown nodules are present (0.6 x 0.6 x 0.4 and 1.0 x 1.0 x 0.9 cm).

SECTION CODE: C1, entire nodule submitted including skin; C2, C3, second nodule, entirely submitted.

(D) EXCISION INTRANSIT METASTASIS LEFT MEDIAL CONDYLE STERILE FOR VACCINE - An ellipse of skin (4.5 x 1.0 cm) excised to a depth of 3.0 cm. Within the underlying subcutaneous tissue is a 0.8 x 0.8 x 0.6 cm spherical mass that has a dark black cut surface. The mass appears free of all soft tissue margins. The majority of the tumor is sent for the vaccine protocol. A representative portion of tumor is submitted in D1 and a representative portion of skin and subcutaneous tissue is in D2.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Released by: MD

[page 2 of 2]
-----END OF REPORT-----

Source: NCI Genomic Data Commons file 9e3b85d7-368b-470a-9c83-e0630c63db79 (TCGA-D3-A1QB.EA89AFF8-7133-4B7F-89E4-9AF1901C300D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).